Somatic mutation profile of tumor specimen TCGA-AA-3664-01A (aliquot TCGA-AA-3664-01A-01W-0900-09) from TCGA case TCGA-AA-3664, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 74.9 years (27,363 days).
Specimen TCGA-AA-3664-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 127c2a14-99ad-4484-ad60-41e8d30d6017.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3664-10A (Blood Derived Normal), aliquot TCGA-AA-3664-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b2d07cb-ded7-49ee-a248-758d5f2ce8cb

The open-access MAF lists 165 somatic variants for this specimen: 122 protein-altering or splice-affecting, 40 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 40, Nonsense Mutation 7, Frame Shift Ins 3, Frame Shift Del 2, 3'UTR 1, In Frame Del 1, Intron 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8307G>A p.W2769* | Nonsense Mutation (SNP) | VAF 70/173 reads (40%) | catalogued as rs778269655, CM960109, COSV53729670; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MCCC1 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 118/218 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs398124352, CM125721, COSV55606726; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AC005833.1 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious, low confidence (0); catalogued as rs756775420, COSV52895128; called by muse, mutect2, varscan2
- ACTN3 | c.348C>A p.S116R | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs1248965969, COSV72207543; called by muse, mutect2, varscan2
- ADAMTS12 | c.3898C>A p.L1300I | Missense Mutation (SNP) | VAF 161/394 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV61256805; called by muse, mutect2, varscan2
- AFDN | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 267/648 reads (41%) | catalogued as rs778113186, COSV60038899; called by muse, mutect2, varscan2
- AL031777.2 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 58/125 reads (46%) | catalogued as rs779876735, COSV61912207; called by muse, mutect2, varscan2
- ATM | c.8082_8084del p.G2695del | In Frame Del (DEL) | VAF 52/136 reads (38%) | catalogued as rs1565540828; called by pindel, varscan2
- ATP6V1B1 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs982193032, COSV52268095; called by muse, mutect2, varscan2
- ATR | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 203/466 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs759350161, COSV63384582; called by muse, mutect2, varscan2
- BMPR1A | c.230del p.I77Kfs*10 | Frame Shift Del (DEL) | VAF 87/148 reads (59%) | catalogued as COSV63135046; called by mutect2, pindel, varscan2
- BMPR1B | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs758706811, COSV52775245, COSV52780828; called by muse, mutect2, varscan2
- BPIFA3 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV64925635; called by muse, mutect2, varscan2
- BRINP1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs548234862, COSV56293434; called by muse, mutect2, varscan2
- C17orf97 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs376770602; called by muse, mutect2, varscan2
- CBLB | c.1960G>A p.V654I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.023); catalogued as COSV51422349; called by muse, mutect2, varscan2
- CCDC138 | c.1937C>T p.S646L | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54564797; called by muse, mutect2, varscan2
- CDH8 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54851718, COSV54864046; called by muse, mutect2, varscan2
- CDH8 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1288307089, COSV54851728; called by muse, mutect2, varscan2
- CERS3 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs138661052, COSV52568776; called by muse, mutect2, varscan2
- CFAP54 | c.7842C>T p.G2614= | Splice Region (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100732925; called by mutect2, varscan2
- CHRDL1 | c.211C>T p.R71* (on ENST00000372045; = p.R77* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 432/461 reads (94%) | catalogued as rs775515705, CM148186, COSV54323255; called by muse, mutect2, varscan2
- CLEC7A | c.625A>G p.T209A (on ENST00000304084 / NM_197947.3; = p.T163A on NM_022570.5) | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV53721346; called by muse, mutect2, varscan2
- CLSPN | c.1882T>C p.F628L | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0.122); catalogued as COSV52047552; called by muse, mutect2, varscan2
- CNTLN | c.3408A>G p.I1136M | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV52068484; called by muse, mutect2, varscan2
- CNTN4 | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 68/452 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.321); catalogued as rs760085098, COSV61868851; called by muse, mutect2, varscan2
- COL15A1 | c.1834G>A p.G612S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as rs1402625709, COSV66641767; called by muse, mutect2, varscan2
- COL5A3 | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs900091483, COSV53407089; called by muse, mutect2, varscan2
- COX4I1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs772180664, COSV53665685; called by muse, mutect2, varscan2
- CRIM1 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs767565422, COSV54860276; called by muse, mutect2, varscan2
- CSMD1 | c.6565T>G p.F2189V (on ENST00000520002; = p.F2188V on NM_033225.6) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV59289644; called by muse, mutect2, varscan2
- CSMD2 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs763406964, COSV53885577; called by muse, mutect2, varscan2
- CTNNA2 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63550258; called by muse, mutect2, varscan2
- CUX1 | c.2744C>T p.P915L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs1164065810, COSV52891198; called by muse, mutect2, varscan2
- CXXC4 | c.865T>G p.S289A | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0.122); catalogued as rs751412118, COSV67295901; called by muse, mutect2, varscan2
- DCTN1 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 137/275 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV62619753; called by muse, mutect2, varscan2
- DEFB118 | c.78dup p.C27Mfs*34 | Frame Shift Ins (INS) | VAF 112/234 reads (48%) | catalogued as rs750510475; called by mutect2, varscan2
- DLG5 | c.3910C>T p.Q1304* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV64947023; called by muse, mutect2, varscan2
- DNAH10 | c.11117G>A p.R3706Q (on ENST00000409039; = p.R3645Q on NM_207437.3) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1282427153, COSV68989032; called by muse, mutect2, varscan2
- DOCK1 | c.3845A>G p.H1282R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs1380553869, COSV54731882; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1157558201, COSV57514641; called by muse, mutect2, varscan2
- GDF10 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1555207627; called by muse, mutect2, varscan2
- GNE | c.116G>A p.R39Q (on ENST00000396594 / NM_001128227.3; = p.R8Q on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs763057654, COSV64951324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR19 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60123029; called by muse, mutect2, varscan2
- HDAC9 | c.3090G>T p.L1030F (on ENST00000441542 / NM_178425.3; = p.L1027F on NM_178423.3) | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs531869853, COSV67768167; called by muse, mutect2, varscan2
- HEATR5A | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs757173902, COSV66338861; called by muse, mutect2, varscan2
- HFE | c.317T>G p.M106R | Missense Mutation (SNP) | VAF 115/285 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as COSV58512605; called by muse, mutect2, varscan2
- HIVEP2 | c.4368G>T p.Q1456H | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50006151; called by muse, mutect2, varscan2
- HSPG2 | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1183271864, COSV65969502; called by muse, mutect2, varscan2
- IGFBP2 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408241472, COSV52079580; called by muse, mutect2, varscan2
- ITPR1 | c.1301C>T p.P434L (on ENST00000354582; = p.P419L on NM_002222.7) | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56971988; called by muse, mutect2, varscan2
- KCNK2 | c.820G>T p.A274S (on ENST00000444842 / NM_001017425.3; = p.A259S on NM_014217.4) | Missense Mutation (SNP) | VAF 233/435 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV67203724; called by muse, mutect2, varscan2
- KIF3A | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771666064, COSV101109213, COSV66413083; called by muse, mutect2, varscan2
- KIF5C | c.2031G>A p.M677I | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV68480081; called by muse, mutect2, varscan2
- LAMA3 | c.7235G>A p.G2412E (on ENST00000313654 / NM_198129.4; = p.G803E on NM_000227.6) | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760183407, COSV99333891; called by muse, varscan2
- LGALSL | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99482381; called by muse, mutect2
- LRP12 | c.650A>C p.Y217S | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52626172; called by muse, mutect2, varscan2
- LVRN | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762126747, COSV63496384; called by muse, mutect2, varscan2
- MARCO | c.1293C>A p.N431K | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.849); catalogued as COSV59052349; called by muse, mutect2, varscan2
- MTERF3 | c.893T>A p.M298K | Missense Mutation (SNP) | VAF 107/152 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV54632075; called by muse, mutect2, varscan2
- MXRA5 | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 65/80 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54226239; called by muse, mutect2, varscan2
- NAIP | c.340A>G p.I114V | Missense Mutation (SNP) | VAF 93/194 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV52000679; called by muse, mutect2, varscan2
- NDUFAF4 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 149/186 reads (80%) | SIFT tolerated (0.49); PolyPhen benign (0.054); catalogued as rs1249227025, COSV60213760; called by muse, mutect2, varscan2
- NHLRC3 | c.973G>C p.A325P | Missense Mutation (SNP) | VAF 171/325 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65462636; called by muse, mutect2, varscan2
- NOX4 | c.1441A>G p.N481D | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV54448114; called by muse, mutect2, varscan2
- NPHS1 | c.1376C>A p.T459N | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV62286657; called by muse, mutect2, varscan2
- NRDE2 | c.1865A>G p.Q622R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs765622805, COSV62962324; called by muse, mutect2, varscan2
- NRSN1 | c.247G>C p.G83R | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101027200; called by muse, mutect2, varscan2
- NTRK3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs201426743, COSV58111825; called by muse, mutect2, varscan2
- OR10AG1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as rs150679428, COSV56634488; called by muse, varscan2
- OR4M1 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 165/597 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60059829; called by muse, mutect2, varscan2
- OR5T2 | c.284A>G p.H95R | Missense Mutation (SNP) | VAF 118/296 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV100506799; called by muse, varscan2
- OR6C76 | c.706T>C p.S236P | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV60388706; called by muse, mutect2, varscan2
- OR6M1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776077538, COSV100484161, COSV58432904; called by muse, mutect2, varscan2
- PARVB | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs750285011, COSV58684424; called by muse, mutect2, varscan2
- PCDHGA9 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1396426480, COSV53908745; called by muse, mutect2, varscan2
- PLXNA4 | c.5679C>A p.D1893E | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58108617; called by muse, mutect2, varscan2
- POSTN | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs1285552885, COSV65712077; called by muse, mutect2, varscan2
- PPFIA4 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs561537732, COSV99829480; called by muse, mutect2, varscan2
- PPP4R1 | c.2644C>T p.R882* (on ENST00000400556 / NM_001042388.3; = p.R865* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 68/185 reads (37%) | catalogued as COSV53280295, COSV53280679; called by muse, mutect2, varscan2
- PRG2 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV61293150; called by muse, mutect2, varscan2
- PROCA1 | c.880G>A p.E294K (on ENST00000439862 / NM_001366301.1; = p.E266K on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/239 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs760322267, COSV56385431; called by muse, mutect2, varscan2
- PTH2R | c.580A>T p.I194F | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55914373; called by muse, mutect2, varscan2
- RAB11B | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as COSV60085314; called by muse, mutect2, varscan2
- RAD51C | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881932, COSV61675832; ClinVar: likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- RD3 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.463); catalogued as COSV65361967; called by muse, mutect2, varscan2
- RELN | c.4807C>A p.Q1603K | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.022); catalogued as COSV58988650, COSV58990414; called by muse, mutect2, varscan2
- RFX2 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as rs201817157, COSV57939613; called by muse, mutect2, varscan2
- RSPO1 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs377442675; called by muse, mutect2, varscan2
- SBK1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV59396171; called by muse, mutect2, varscan2
- SDK1 | c.943T>A p.C315S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101268732; called by muse, mutect2, varscan2
- SLC38A2 | c.1297A>G p.T433A | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as rs773343163, COSV56744241; called by muse, mutect2, varscan2
- SLC43A1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.021); catalogued as rs202015221, COSV53557764; called by muse, mutect2, varscan2
- SLC7A10 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200120655, COSV53502697; called by muse, mutect2, varscan2
- SMAP2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV65531421; called by muse, mutect2, varscan2
- SMARCC1 | c.2860G>A p.A954T | Missense Mutation (SNP) | VAF 111/289 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1216431072, COSV54377825; called by muse, mutect2, varscan2
- SMPD1 | c.871C>A p.R291S | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100192495, COSV54966742; called by muse, mutect2, varscan2
- SP1 | c.1538C>T p.A513V (on ENST00000327443 / NM_138473.3; = p.A506V on NM_003109.1) | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV59401944; called by muse, mutect2, varscan2
- SPAG11A | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1452766357, COSV100429290; called by mutect2, varscan2
- SPTLC2 | c.1628G>T p.R543L | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV53638633, COSV53640695; called by muse, mutect2, varscan2
- STOX1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs770130603, COSV53813330; called by muse, mutect2, varscan2
- SUSD5 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs369886584; called by muse, mutect2, varscan2
- SYNE1 | c.6502A>G p.K2168E (on ENST00000367255 / NM_182961.4; = p.K2175E on NM_033071.3) | Missense Mutation (SNP) | VAF 107/126 reads (85%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV54921420; called by muse, mutect2, varscan2
- TAS2R10 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as rs201510957; called by muse, mutect2, varscan2
- TFAP2D | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV50409297; called by muse, mutect2, varscan2
- TOX | c.733A>G p.K245E | Missense Mutation (SNP) | VAF 68/309 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV63843187, COSV63845127; called by muse, mutect2, varscan2
- TTC24 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV63997331; called by muse, mutect2, varscan2
- TULP1 | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV57692042; called by muse, mutect2, varscan2
- UGDH | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57096850; called by muse, mutect2
- UNC13C | c.2905C>T p.R969C | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs191961732; called by muse, mutect2, varscan2
- VPS50 | c.247T>A p.L83M | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV52493063; called by muse, mutect2, varscan2
- WNT7A | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456656577, COSV53197111, COSV99541812; called by muse, mutect2, varscan2
- ZFP28 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs775754596, COSV56734840; called by muse, mutect2, varscan2
- ZNF135 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV57880503; called by muse, mutect2
- ZNF423 | c.2738G>A p.R913Q (on ENST00000563137 / NM_001379286.1; = p.R905Q on NM_015069.4) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.54); PolyPhen benign (0.106); catalogued as rs777432098, COSV52179326; called by muse, mutect2, varscan2
- ZNF536 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62819674; called by muse, mutect2, varscan2
- ZYG11B | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.239); catalogued as COSV53750530; called by muse, mutect2, varscan2
- MARCHF10 | c.290del p.P97Qfs*16 | Frame Shift Del (DEL) | VAF 40/130 reads (31%) | called by mutect2, pindel, varscan2
- PDGFRB | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.022); called by muse, mutect2
- PIK3R1 | c.273_274dup p.P92Hfs*23 | Frame Shift Ins (INS) | VAF 35/111 reads (32%) | called by mutect2, pindel, varscan2
- TFEC | c.422dup p.D142Gfs*7 | Frame Shift Ins (INS) | VAF 31/87 reads (36%) | called by mutect2, varscan2
- ABCC10 | c.1269C>T p.F423= (on ENST00000372530 / NM_001198934.2; = p.F380= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs776357831, COSV55085097; called by muse, mutect2, varscan2
- AHNAK2 | c.9525C>T p.A3175= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as COSV60909214; called by muse, varscan2
- ANKRD11 | c.6417G>A p.P2139= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs755356592, COSV56356146; called by muse, mutect2, varscan2
- ASTN1 | c.2019C>T p.D673= | Silent (SNP) | VAF 39/192 reads (20%) | catalogued as COSV56062762; called by muse, mutect2, varscan2
- BPIFB3 | c.750C>T p.I250= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs934156492, COSV64956844; called by muse, mutect2, varscan2
- BRINP3 | c.1335C>T p.D445= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as rs746938927, COSV66514992; called by muse, mutect2, varscan2
- CHRM1 | c.96G>A p.T32= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs373462832, COSV100186079; called by muse, mutect2, varscan2
- CLIP1 | c.2478G>A p.Q826= (on ENST00000620786 / NM_001247997.1; = p.Q815= on NM_002956.2) | Silent (SNP) | VAF 65/237 reads (27%) | catalogued as rs773264545, COSV56798353; called by muse, mutect2, varscan2
- DHX16 | c.2403C>T p.A801= | Silent (SNP) | VAF 60/132 reads (45%) | catalogued as COSV53312814; called by muse, mutect2
- DHX34 | c.2010G>C p.R670= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV60894565, COSV60897222; called by muse, mutect2, varscan2
- DTX1 | c.309G>A p.P103= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs1215347941, COSV57495854, COSV99986568; called by muse, mutect2, varscan2
- EPHA5 | c.3048G>A p.Q1016= | Silent (SNP) | VAF 47/94 reads (50%) | catalogued as COSV56633729; called by muse, mutect2, varscan2
- G0S2 | c.192G>A p.A64= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1184577979, COSV65433089; called by muse, mutect2, varscan2
- GRM3 | c.768C>T p.Y256= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as COSV64468079; called by muse, mutect2, varscan2
- HERC5 | c.2637G>A p.A879= | Silent (SNP) | VAF 117/344 reads (34%) | catalogued as rs761284663, COSV52037717; called by muse, mutect2, varscan2
- KCNH6 | c.1302C>T p.I434= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs190171184, COSV59001185; called by muse, mutect2, varscan2
- KCTD19 | c.2358G>A p.T786= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs757212801, COSV58570978; called by muse, mutect2, varscan2
- KIF20B | c.3750A>G p.E1250= (on ENST00000371728 / NM_001284259.2; = p.E1210= on NM_016195.4) | Silent (SNP) | VAF 69/171 reads (40%) | catalogued as COSV53303195; called by muse, mutect2, varscan2
- KYAT3 | c.18G>A p.R6= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as COSV53098980; called by muse, mutect2, varscan2
- LAIR1 | c.840G>A p.T280= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as rs746249343, COSV57306180; called by muse, mutect2, varscan2
- MYOM2 | c.2100C>T p.D700= | Silent (SNP) | VAF 57/135 reads (42%) | catalogued as rs1052447579, COSV50703544; called by muse, mutect2, varscan2
- NLRP3 | c.2940C>T p.G980= | Silent (SNP) | VAF 82/144 reads (57%) | catalogued as rs199649583, COSV100275020, COSV60220925; ClinVar: likely benign; called by muse, mutect2, varscan2
- PGM5 | c.1026C>A p.T342= | Silent (SNP) | VAF 73/253 reads (29%) | catalogued as COSV101123340; called by muse, mutect2, varscan2
- PHYKPL | c.396C>T p.D132= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs528494634, COSV57423122; called by muse, mutect2, varscan2
- RAD50 | c.1170A>G p.E390= | Silent (SNP) | VAF 50/143 reads (35%) | catalogued as COSV54748417; called by muse, mutect2, varscan2
- RUNX1T1 | c.1311G>A p.A437= (on ENST00000265814 / NM_001198628.1; = p.A410= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 163/269 reads (61%) | catalogued as rs780217648, COSV56139371; called by muse, mutect2, varscan2
- SDK2 | c.2100C>T p.S700= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs201245646; called by muse, mutect2, varscan2
- SLC44A2 | c.660C>T p.L220= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs148167135; called by muse, mutect2, varscan2
- TBC1D4 | c.1008A>G p.R336= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV66487866; called by muse, mutect2, varscan2
- TBC1D7 | c.696T>C p.C232= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV58243471; called by muse, mutect2, varscan2
- TCF21 | c.186G>A p.A62= | Silent (SNP) | VAF 49/61 reads (80%) | catalogued as rs1333572678, COSV52817951; called by muse, mutect2, varscan2
- TGM2 | c.801C>T p.H267= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs749547512, COSV63931139; called by muse, mutect2
- TMEM185A | c.939G>A p.P313= | Silent (SNP) | VAF 68/233 reads (29%) | catalogued as rs1429270978; called by muse, mutect2, varscan2
- TMEM216 | c.366C>A p.G122= (on ENST00000515837 / NM_001173990.3; = p.G61= on NM_016499.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/263 reads (39%) | catalogued as COSV58425846; called by muse, mutect2, varscan2
- TUBA3C | c.330C>T p.I110= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as rs1486793465, COSV67138923; called by muse, mutect2, varscan2
- UTP14C | c.936C>A p.A312= | Silent (SNP) | VAF 181/250 reads (72%) | catalogued as COSV73000586; called by muse, mutect2, varscan2
- VANGL2 | c.762C>T p.T254= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as rs139084368; called by muse, mutect2, varscan2
- VWF | c.6879G>A p.T2293= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs764917249, COSV54613252; called by muse, mutect2, varscan2
- XRN2 | c.1083C>T p.D361= | Silent (SNP) | VAF 100/194 reads (52%) | catalogued as COSV65868293; called by muse, mutect2, varscan2
- ZNF682 | c.300G>A p.L100= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as rs749862860, COSV62066254, COSV62066884; called by muse, mutect2, varscan2
- CPLANE1 | c.*4681A>G | 3'UTR (SNP) | VAF 34/90 reads (38%) | catalogued as COSV57054050; called by muse, mutect2, varscan2
- MSRB3 | c.98-18216A>T | Intron (SNP) | VAF 49/128 reads (38%) | catalogued as COSV57588282; called by muse, mutect2, varscan2
- SNORD116-2 | n.32C>A | RNA (SNP) | VAF 59/153 reads (39%) | catalogued as rs753087750; called by muse, mutect2, varscan2
